Somatic mutation profile of tumor specimen TCGA-DE-A4M8-01A (aliquot TCGA-DE-A4M8-01A-21D-A257-08) from TCGA case TCGA-DE-A4M8, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 61.2 years (22,357 days).
Specimen TCGA-DE-A4M8-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 02946a95-0845-4f8e-b2ce-3c827424520a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DE-A4M8-10A (Blood Derived Normal), aliquot TCGA-DE-A4M8-10A-01D-A25A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/500a1ec1-741c-492d-94eb-4d79ec97c405

The open-access MAF lists 10 somatic variants for this specimen: 7 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 7, Silent 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH8 | c.1420C>A p.H474N | Missense Mutation (SNP) | VAF 16/141 reads (11%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.484); catalogued as COSV54907635; called by muse, mutect2, varscan2
- KDR | c.3854T>C p.M1285T | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.024); catalogued as COSV55778924; called by muse, mutect2
- POFUT2 | c.949C>T p.R317C | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.878); catalogued as rs758098497, COSV57959953; called by muse, mutect2, varscan2
- TMSB15A | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 9/95 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.187); catalogued as rs782471974, COSV56818729; called by muse, mutect2, varscan2
- VWA2 | c.1253G>C p.G418A | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53912384; called by muse, mutect2, varscan2
- IGKV2D-24 | c.350C>T p.T117I | Missense Mutation (SNP) | VAF 19/115 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- KBTBD2 | c.383T>C p.I128T | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.61); called by muse, mutect2
- FBXO3 | c.495G>A p.L165= | Silent (SNP) | VAF 3/29 reads (10%) | catalogued as COSV55768561; called by muse, mutect2
- PCDH12 | c.2985A>G p.A995= | Silent (SNP) | VAF 19/101 reads (19%) | catalogued as COSV51525417; called by muse, mutect2, varscan2
- SYN2 | c.462G>A p.V154= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV70286874; called by muse, mutect2, varscan2
